Somatic mutation profile of tumor specimen ALCH-B3I9-TTP1-A (aliquot ALCH-B3I9-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3I9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.2 years (21,631 days).
Specimen ALCH-B3I9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08e0b0a1-5d6b-4ab0-adf3-13b590796d48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3I9-NB1-A (Blood Derived Normal), aliquot ALCH-B3I9-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0809cefd-0007-491e-ba2c-59bf60fea457

The open-access MAF lists 308 somatic variants for this specimen: 211 protein-altering or splice-affecting, 64 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 64, Intron 17, Splice Site 8, Nonsense Mutation 8, 3'UTR 5, Frame Shift Del 5, RNA 4, 5'UTR 3, Frame Shift Ins 2, In Frame Del 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 81/302 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1856A>G p.Q619R | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99445680; called by muse, mutect2
- ABHD17A | c.364G>C p.V122L (on ENST00000292577 / NM_001130111.2; = p.V173L on NM_031213.4) | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV51748994; called by muse, mutect2
- ABL2 | c.772A>G p.T258A (on ENST00000502732 / NM_007314.4; = p.T243A on NM_005158.5) | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs888202853; called by muse, mutect2, varscan2
- ACVR1 | c.1395+1G>T p.X465_splice | Splice Site (SNP) | VAF 50/439 reads (11%) | catalogued as COSV55117590; called by muse, mutect2, varscan2
- ADCY1 | c.3276G>T p.M1092I | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV52038622; called by muse, mutect2, varscan2
- ADGB | c.4835C>A p.A1612D | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as rs780545308; called by muse, mutect2
- AKT2 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1231123715; called by muse, mutect2, varscan2
- ARHGAP23 | c.234G>C p.E78D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1473883451; called by muse, mutect2, varscan2
- ARSL | c.1040T>A p.L347H | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101140588; called by muse, mutect2, varscan2
- ARX | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as rs1475419182; called by muse, mutect2
- ATRX | c.4680G>T p.L1560F | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64872324; called by muse, mutect2
- BRD4 | c.3753G>T p.E1251D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.899); catalogued as COSV54594295; called by mutect2, varscan2
- CD27 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV56946440; called by muse, mutect2, varscan2
- CDH9 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50411689; called by muse, mutect2
- CFAP58 | c.1305C>G p.I435M | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1435739831; called by muse, mutect2, varscan2
- CRLF1 | c.397C>T p.L133= | Splice Region (SNP) | VAF 6/55 reads (11%) | catalogued as rs747750093; called by mutect2, varscan2
- CROT | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs776822170; called by muse, mutect2, varscan2
- CRX | c.362C>A p.A121E | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as CM128839, COSV55759532; called by muse, mutect2, varscan2
- CTSK | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 64/382 reads (17%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as rs949980727; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 6/43 reads (14%) | catalogued as rs754135731; called by muse*, mutect2, varscan2*
- DNAH2 | c.6983C>T p.S2328F | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV66725600; called by muse, mutect2, varscan2
- DNAH7 | c.5905C>G p.Q1969E | Missense Mutation (SNP) | VAF 40/435 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs201839382; called by muse, mutect2
- DNAH8 | c.12330G>A p.M4110I | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59448052; called by muse, mutect2, varscan2
- EHBP1L1 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs902837840, COSV58573937; called by muse, mutect2, varscan2
- ENOX2 | c.832C>T p.R278* (on ENST00000338144 / NM_001382520.1; = p.R249* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/157 reads (17%) | catalogued as rs751141125, COSV57647897; called by muse, mutect2, varscan2
- EYS | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 43/416 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs1294478596; called by muse, mutect2
- FRYL | c.8702T>C p.I2901T | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs918355082; called by muse, mutect2
- GRIN2B | c.3679A>G p.T1227A | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV74206244; called by muse, mutect2
- HNRNPA2B1 | c.226G>A p.D76N (on ENST00000354667 / NM_031243.3; = p.D64N on NM_002137.4) | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61160210, COSV61160744; called by muse, mutect2
- KCNJ3 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.14); catalogued as COSV54531182; called by muse, mutect2
- KDM3A | c.2300A>G p.K767R | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.694); catalogued as COSV100460223; called by muse, mutect2, varscan2
- KMT2D | c.15490C>T p.Q5164* | Nonsense Mutation (SNP) | VAF 20/154 reads (13%) | catalogued as rs1214915183, COSV99985936; called by muse, mutect2, varscan2
- KRT74 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV99977427; called by muse, mutect2
- LRIG1 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs1219290074; called by muse, mutect2, varscan2
- LRRTM4 | c.375C>A p.H125Q | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as rs1344631056, COSV69140741; called by muse, mutect2, varscan2
- MCF2L | c.2113G>A p.D705N (on ENST00000375608; = p.D673N on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV99996026; called by muse, mutect2, varscan2
- MROH2B | c.2322C>A p.F774L | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV68187564; called by muse, mutect2, varscan2
- MUC17 | c.6706G>A p.E2236K | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60284165; called by muse, mutect2
- NCOA3 | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 15/298 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs1456661218; called by muse, mutect2
- NFASC | c.2758C>T p.P920S (on ENST00000339876 / NM_001378329.1; = p.P1023S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs902094913; called by muse, mutect2, varscan2
- NR2E1 | c.746A>T p.N249I | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV64561705; called by muse, mutect2
- NR2E3 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1174147743; called by muse, mutect2, varscan2
- P2RY14 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs575550811, COSV99855346; called by muse, mutect2, varscan2
- PCNT | c.2684A>G p.E895G | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs1388436050; called by muse, mutect2, varscan2
- POU5F2 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV67942068; called by muse, mutect2
- PPP1R42 | c.421C>A p.L141I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV100221175; called by muse, mutect2, varscan2
- PUDP | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 15/280 reads (5%) | catalogued as COSV66904792; called by muse, mutect2
- RGS2 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs142499684; called by muse, mutect2
- RPL26 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV53446831; called by muse, mutect2
- RPP40 | c.430T>G p.F144V | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV60291940; called by muse, mutect2, varscan2
- SEMA6D | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs764238748; called by muse, mutect2, varscan2
- SLC4A8 | c.2416G>A p.V806I | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1045782037; called by muse, mutect2, varscan2
- TRIM23 | c.899G>A p.C300Y | Missense Mutation (SNP) | VAF 19/396 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1561747583; called by muse, mutect2
- TRPM8 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 18/289 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs893643190; called by muse, mutect2
- TTI2 | c.1439T>G p.I480S | Missense Mutation (SNP) | VAF 15/498 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs945975300, COSV100659808; called by muse, mutect2
- TUB | c.973G>C p.G325R (on ENST00000299506 / NM_177972.3; = p.G380R on NM_003320.4) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs759795167; called by muse, mutect2, varscan2
- UBASH3B | c.1349G>C p.R450T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV99417724; called by muse, mutect2, varscan2
- VAV3 | c.1462G>C p.D488H | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV58380137; called by muse, mutect2, varscan2
- WTAP | c.482G>T p.C161F | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV100493427; called by muse, mutect2, varscan2
- ZBTB16 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 45/389 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs774495039; called by muse, mutect2, varscan2
- ZFHX4 | c.10439T>A p.M3480K | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV99255885; called by muse, mutect2
- ZIC1 | c.699G>C p.E233D | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.208); catalogued as rs1305930884; called by muse, mutect2, varscan2
- ZRANB1 | c.1292G>C p.R431P | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV62843013; called by muse, mutect2, varscan2
- AC132807.2 | n.130-1G>C | Splice Site (SNP) | VAF 35/232 reads (15%) | called by muse, mutect2, varscan2
- ACSL6 | c.1244T>A p.L415H (on ENST00000379240; = p.L440H on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADCY2 | c.2339C>A p.T780N | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- AHNAK | c.10735A>C p.I3579L | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- AKAP11 | c.581T>G p.L194* | Nonsense Mutation (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- ANKRD26 | c.3654+2T>C p.X1218_splice | Splice Site (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2, varscan2
- ANKRD31 | c.2819dup p.M940Ifs*10 | Frame Shift Ins (INS) | VAF 28/144 reads (19%) | called by mutect2, pindel, varscan2
- APLF | c.1438G>C p.D480H | Missense Mutation (SNP) | VAF 35/383 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APLP2 | c.2074A>G p.S692G | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2
- ARHGAP12 | c.1111C>G p.Q371E | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.404); called by muse, mutect2
- ARHGAP35 | c.2477_2489del p.I826Rfs*57 | Frame Shift Del (DEL) | VAF 34/195 reads (17%) | called by mutect2, pindel, varscan2
- ASTN1 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP10A | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BOD1L1 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC170 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 50/468 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- CCNJL | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.257); called by mutect2, varscan2
- CELSR1 | c.7898C>G p.S2633C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); called by muse, mutect2
- CEP95 | c.1387T>A p.L463M | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- CEP97 | c.407T>A p.I136K | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- CFAP47 | c.657-1G>C p.X219_splice | Splice Site (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- CHD7 | c.3745_3746insT p.R1249Lfs*14 | Frame Shift Ins (INS) | VAF 13/91 reads (14%) | called by mutect2, pindel, varscan2
- CHRM3 | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- CHST7 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNEP1R1 | c.118G>T p.V40F (on ENST00000427478 / NM_001281789.1; = p.V57F on NM_153261.5) | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); called by muse, mutect2
- CNTNAP4 | c.671G>T p.R224M | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.142); called by muse, mutect2
- COL12A1 | c.8365G>T p.G2789C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A6 | c.1088T>A p.F363Y | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2
- COL7A1 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2
- CUL3 | c.1464del p.R488Sfs*11 | Frame Shift Del (DEL) | VAF 28/222 reads (13%) | called by mutect2, pindel, varscan2
- CYTH3 | c.854G>T p.R285L (on ENST00000396741; = p.R284L on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- DDX46 | c.2747A>C p.Q916P | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- DGKB | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DHX58 | c.1680G>C p.M560I | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DIRAS3 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- DNHD1 | c.5489C>G p.P1830R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNTT | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DST | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- EBP | c.339-2A>T p.X113_splice | Splice Site (SNP) | VAF 22/273 reads (8%) | called by muse, mutect2
- EPHA3 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHX1 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FAM170A | c.292del p.R98Afs*22 | Frame Shift Del (DEL) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- FAM71C | c.141G>C p.E47D | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- FAM83H | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- FBN1 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2
- FMN2 | c.4316A>T p.Y1439F | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.47); called by muse, mutect2
- FOXB2 | c.277T>A p.C93S | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2
- FSCN1 | c.86_106del p.F29_A35del | In Frame Del (DEL) | VAF 12/109 reads (11%) | called by mutect2, pindel
- FUT7 | c.772_773del p.P258Tfs*5 | Frame Shift Del (DEL) | VAF 48/150 reads (32%) | called by mutect2, pindel, varscan2
- GAA | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- GOLGB1 | c.3452G>A p.C1151Y | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- GPR174 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPX6 | c.626C>A p.S209* | Nonsense Mutation (SNP) | VAF 27/159 reads (17%) | called by muse, mutect2, varscan2
- GRIN2A | c.3557T>A p.L1186H | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- HNRNPCL2 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- HSF1 | c.134A>T p.H45L | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- IGKV2D-26 | c.149T>A p.L50Q | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- IRF3 | c.221C>A p.P74Q | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- ITPR2 | c.8050C>A p.L2684M | Missense Mutation (SNP) | VAF 24/251 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- KCNJ10 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); called by muse, mutect2
- KIF5A | c.2517G>T p.Q839H | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLHL4 | c.1279A>T p.T427S | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2
- KLHL4 | c.1280C>A p.T427N | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- LAMA3 | c.9887G>A p.W3296* (on ENST00000313654 / NM_198129.4; = p.W1687* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 62/535 reads (12%) | called by muse, mutect2, varscan2
- LAMA4 | c.4373A>T p.H1458L (on ENST00000230538 / NM_001105206.3; = p.H1451L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LILRA2 | c.953-1G>C p.X318_splice | Splice Site (SNP) | VAF 41/164 reads (25%) | called by muse, mutect2, varscan2
- LOXHD1 | c.4500G>C p.E1500D | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); called by muse, mutect2
- LRRK2 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 34/260 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- MACF1 | c.15173G>C p.R5058T (on ENST00000372915; = p.R2991T on NM_012090.5) | Missense Mutation (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- MCCC1 | c.1726A>C p.M576L | Missense Mutation (SNP) | VAF 36/512 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- MCF2L | c.2158G>C p.D720H (on ENST00000375608; = p.D688H on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MCF2L2 | c.2761T>A p.F921I | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- MIIP | c.299G>A p.C100Y | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, varscan2
- MORC1 | c.458C>G p.T153S | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2
- MROH2B | c.3575A>G p.Q1192R | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.201); called by muse, mutect2
- MS4A18 | c.409T>C p.F137L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- MSL2 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2
- MTIF2 | c.852C>G p.I284M | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NANOG | c.102C>A p.N34K | Missense Mutation (SNP) | VAF 25/327 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.035); called by muse, mutect2
- NANOS2 | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAPG2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 24/376 reads (6%) | called by muse, mutect2
- NLGN4X | c.379T>C p.W127R | Missense Mutation (SNP) | VAF 13/372 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- NMU | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, varscan2
- NOX5 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NPAP1 | c.3032C>A p.P1011H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- NUP88 | c.338A>G p.Q113R | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- OLFML3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2
- OR52E6 | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- OR5J2 | c.243G>C p.M81I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- OR6C1 | c.439T>C p.W147R | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2
- PABPC4L | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PADI4 | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHB14 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCLO | c.2325A>T p.K775N | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2
- PCSK5 | c.2213G>T p.R738L | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- PEG3 | c.144G>T p.R48S | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- PKD1L3 | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.191); called by muse, mutect2
- PLCH1 | c.998C>A p.A333E (on ENST00000340059 / NM_001130960.2; = p.A345E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLXNA3 | c.4609del p.R1537Afs*2 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- POLB | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 25/251 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- PTCH1 | c.2773G>T p.A925S | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PTPRD | c.1730C>A p.P577Q | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAB27B | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- RAB41 | c.650G>C p.G217A (on ENST00000374473 / NM_001363807.1; = p.G216A on NM_001032726.3) | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2
- RIMKLB | c.366G>T p.L122F | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RSPO2 | c.730T>C p.*244Qext*41 | Nonstop Mutation (SNP) | VAF 31/163 reads (19%) | called by muse, mutect2, varscan2
- RSPO3 | c.596G>C p.C199S | Missense Mutation (SNP) | VAF 96/394 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RUBCN | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 26/321 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SBF2 | c.1649T>G p.L550R | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SELL | c.289C>G p.R97G (on ENST00000650983; = p.R84G on NM_000655.5) | Missense Mutation (SNP) | VAF 51/424 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SGK1 | c.973A>G p.R325G | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.782); called by mutect2, varscan2
- SLC22A10 | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 13/339 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.768); called by muse, mutect2
- SLC35F4 | c.1247T>A p.L416Q (on ENST00000339762 / NM_001352015.2; = p.L380Q on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC44A3 | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC66A2 | c.796A>G p.T266A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- SPON1 | c.513T>A p.F171L | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- SSX1 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 15/275 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2
- STS | c.45G>T p.E15D | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- STXBP5 | c.2470G>T p.V824L (on ENST00000321680 / NM_001127715.2; = p.V788L on NM_139244.4) | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SVEP1 | c.2789G>C p.R930T | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SYTL5 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- TAS2R16 | c.392T>G p.L131R | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TAT | c.1225-1G>A p.X409_splice | Splice Site (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- TCF4 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TDRD3 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TGFBR3 | c.2018G>T p.R673I | Missense Mutation (SNP) | VAF 44/444 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- TGFBRAP1 | c.1521+1G>A p.X507_splice | Splice Site (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- TMC1 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 40/231 reads (17%) | called by muse, mutect2, varscan2
- TMEFF1 | c.1091A>T p.Q364L | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TNFRSF11B | c.205T>A p.Y69N | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TNRC6B | c.2671G>A p.D891N | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- TPM3 | c.182A>G p.Y61C | Missense Mutation (SNP) | VAF 55/428 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- TRAPPC9 | c.824C>G p.T275S | Missense Mutation (SNP) | VAF 60/332 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM6 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.99448G>T p.D33150Y (on ENST00000591111; = p.D25726Y on NM_003319.4) | Missense Mutation (SNP) | VAF 29/274 reads (11%) | PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- UBR3 | c.3338A>G p.D1113G | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2
- ULBP2 | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 40/564 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- UNC13C | c.1850C>G p.T617S | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2
- UNC5D | c.1248C>A p.D416E | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- USP53 | c.696A>G p.I232M | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- WDHD1 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 32/552 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.243); called by muse, mutect2
- YAF2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- YTHDF2 | c.1115G>C p.G372A | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.033); called by muse, mutect2
- ZIC3 | c.1182C>A p.D394E | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.615); called by muse, mutect2
- ZNF287 | c.414C>G p.N138K | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZNF398 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by mutect2, varscan2
- ZNF527 | c.1627C>G p.Q543E | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF546 | c.2024G>C p.S675T | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- ABI2 | c.1437T>C p.Y479= (on ENST00000295851 / NM_001375719.1; = p.Y441= on NM_005759.7 and 35 other RefSeq transcripts) | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as rs201919959; called by muse, mutect2, varscan2
- ADAMTS13 | c.1149G>A p.V383= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as rs1423674564; called by muse, mutect2, varscan2
- ADGRG1 | c.1920C>G p.L640= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as COSV65635266, COSV65636572; called by muse, mutect2
- AGT | c.444G>T p.L148= | Silent (SNP) | VAF 37/322 reads (11%) | called by muse, mutect2, varscan2
- ANKRD27 | c.681C>T p.Y227= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as rs200412555, COSV60133166; called by muse, mutect2
- ASTN1 | c.1377C>A p.A459= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV56061684; called by muse, mutect2
- BICDL1 | c.18G>C p.L6= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- C5 | c.4797C>G p.T1599= | Silent (SNP) | VAF 24/411 reads (6%) | called by muse, mutect2
- CD69 | c.411T>C p.G137= | Silent (SNP) | VAF 36/329 reads (11%) | called by muse, mutect2, varscan2
- CD7 | c.45G>T p.A15= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs374780838; called by muse, mutect2
- CDK6 | c.492C>T p.F164= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as rs774750394, COSV56005149; called by muse, mutect2
- CEP112 | c.1689A>G p.G563= | Silent (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2, varscan2
- CFD | c.192G>C p.A64= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs754456696; called by mutect2, varscan2
- DAAM2 | c.1779C>T p.L593= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as rs903359505; called by muse, mutect2, varscan2
- DCUN1D4 | c.84C>T p.T28= | Silent (SNP) | VAF 11/264 reads (4%) | called by muse, mutect2
- DDX43 | c.1560T>C p.D520= | Silent (SNP) | VAF 12/196 reads (6%) | catalogued as rs1304445048; called by muse, mutect2
- DIDO1 | c.5328G>A p.G1776= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs752039835, COSV99826153; called by muse, mutect2, varscan2
- DSG1 | c.660G>A p.T220= | Silent (SNP) | VAF 24/246 reads (10%) | catalogued as rs199721165; called by muse, mutect2
- EDNRB | c.1314T>A p.T438= (on ENST00000377211 / NM_001201397.1; = p.T348= on NM_000115.5) | Silent (SNP) | VAF 48/420 reads (11%) | called by muse, mutect2, varscan2
- EFCAB5 | c.3096G>A p.L1032= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- EHMT1 | c.1161C>T p.R387= | Silent (SNP) | VAF 26/183 reads (14%) | catalogued as rs759417830; called by muse, mutect2, varscan2
- FBXW9 | c.1254C>T p.S418= (on ENST00000587955; = p.S398= on NM_032301.3) | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs993470140, COSV100981931; called by muse, mutect2
- FOXB2 | c.453C>T p.H151= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- GABRA4 | c.156G>T p.L52= | Silent (SNP) | VAF 43/356 reads (12%) | called by muse, mutect2, varscan2
- GK2 | c.1278A>T p.G426= | Silent (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- GNAS | c.174G>A p.K58= | Silent (SNP) | VAF 18/456 reads (4%) | called by muse, mutect2
- GNS | c.336C>T p.N112= | Silent (SNP) | VAF 18/374 reads (5%) | called by muse, mutect2
- H2AC6 | c.303G>A p.V101= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as rs1413589300; called by muse, mutect2, varscan2
- IMPG1 | c.1074G>T p.L358= | Silent (SNP) | VAF 23/302 reads (8%) | catalogued as rs1326364666, COSV64059348; called by muse, mutect2
- ITGB3 | c.1440C>A p.T480= | Silent (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- MPP7 | c.1656C>T p.F552= | Silent (SNP) | VAF 46/361 reads (13%) | catalogued as rs17853796, COSV61739847; called by muse, mutect2, varscan2
- MRPL1 | c.693C>T p.P231= | Silent (SNP) | VAF 48/358 reads (13%) | called by muse, mutect2, varscan2
- MTHFR | c.897C>T p.I299= | Silent (SNP) | VAF 17/239 reads (7%) | catalogued as rs146025831; called by muse, mutect2
- MYBPC2 | c.3234G>A p.K1078= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- NLRP13 | c.3090G>A p.K1030= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs772453642; called by mutect2, varscan2
- OR51B4 | c.798T>A p.P266= | Silent (SNP) | VAF 26/199 reads (13%) | called by muse, mutect2, varscan2
- PCNX3 | c.1122G>T p.L374= | Silent (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
- PDE1C | c.1158C>T p.L386= | Silent (SNP) | VAF 13/171 reads (8%) | called by muse, mutect2
- PLEKHG1 | c.132C>T p.N44= | Silent (SNP) | VAF 14/216 reads (6%) | catalogued as COSV62045858; called by muse, mutect2
- PLEKHM3 | c.1374G>A p.A458= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs1222598030, COSV101216812; called by muse, mutect2, varscan2
- PRAMEF20 | c.1017G>T p.P339= | Silent (SNP) | VAF 52/304 reads (17%) | catalogued as rs948202258; called by mutect2, varscan2
- PTX3 | c.429G>A p.E143= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1044964753; called by muse, mutect2, varscan2
- RGSL1 | c.2010C>A p.I670= | Silent (SNP) | VAF 34/315 reads (11%) | called by muse, mutect2, varscan2
- RUNDC1 | c.765G>A p.Q255= | Silent (SNP) | VAF 16/446 reads (4%) | called by muse, mutect2
- RYR3 | c.9462C>T p.P3154= (on ENST00000389232; = p.P3155= on NM_001036.6) | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV66800348, COSV66800544; called by muse, mutect2
- SLC5A5 | c.1299G>A p.L433= | Silent (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- SLITRK2 | c.219C>G p.L73= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV59427778; called by muse, mutect2
- SMCO2 | c.24A>G p.L8= | Silent (SNP) | VAF 28/191 reads (15%) | called by muse, mutect2, varscan2
- TBC1D2 | c.1170G>A p.A390= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs1282372881; called by muse, mutect2, varscan2
- TEKT4 | c.1023C>A p.A341= | Silent (SNP) | VAF 13/120 reads (11%) | called by muse, mutect2, varscan2
- THSD7B | c.3067C>A p.R1023= | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as COSV55661886; called by muse, mutect2
- TLK1 | c.2085C>A p.V695= | Silent (SNP) | VAF 19/268 reads (7%) | called by muse, mutect2
- TLK2 | c.291A>T p.G97= | Silent (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- TMEM202 | c.174G>T p.T58= | Silent (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- TRABD2A | c.465T>A p.A155= | Silent (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2, varscan2
- TRAV8-1 | c.276C>A p.S92= | Silent (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- TUBB8 | c.597C>G p.T199= | Silent (SNP) | VAF 36/260 reads (14%) | called by muse, mutect2, varscan2
- UMOD | c.159G>A p.Q53= | Silent (SNP) | VAF 13/169 reads (8%) | called by muse, mutect2
- VPS13A | c.9318G>C p.T3106= | Silent (SNP) | VAF 51/361 reads (14%) | called by muse, mutect2, varscan2
- WDR72 | c.1842G>A p.K614= | Silent (SNP) | VAF 23/224 reads (10%) | called by muse, mutect2, varscan2
- ZMAT3 | c.573G>T p.L191= | Silent (SNP) | VAF 20/310 reads (6%) | catalogued as COSV60995358; called by muse, mutect2
- ZNF469 | c.5274C>T p.P1758= (on ENST00000437464; = p.P1786= on NM_001367624.2) | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- ZNF628 | c.693C>T p.A231= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs1481018431; called by muse, mutect2, varscan2
- ZNF69 | c.435C>T p.I145= (on ENST00000429654 / NM_001364730.1; = p.I131= on NM_021915.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/241 reads (7%) | called by muse, mutect2
- ABI3BP | c.1577-14380G>A | Intron (SNP) | VAF 23/273 reads (8%) | catalogued as rs1008758369, COSV99428725; called by muse, mutect2
- AC092675.1 | n.470T>A | RNA (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- AP000356.3 | chr22:24647084 C>A | 5'Flank (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- ASH1L | c.-352C>T | 5'UTR (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- CCL14 | c.79+811C>G | Intron (SNP) | VAF 14/264 reads (5%) | called by muse, mutect2
- CCNYL1 | c.220+2241G>T | Intron (SNP) | VAF 24/137 reads (18%) | called by muse, mutect2, varscan2
- CDC16 | c.541+21T>G | Intron (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- CIT | c.1402-158C>G | Intron (SNP) | VAF 30/217 reads (14%) | catalogued as rs1297375813; called by muse, mutect2, varscan2
- DCLRE1CP1 | n.168C>A | RNA (SNP) | VAF 8/128 reads (6%) | catalogued as rs1264634222; called by muse, mutect2
- DCLRE1CP1 | n.167C>T | RNA (SNP) | VAF 8/127 reads (6%) | catalogued as rs1206368010; called by muse, mutect2
- EPB41L2 | c.2043+1387C>T | Intron (SNP) | VAF 10/208 reads (5%) | catalogued as rs1415008782; called by muse, mutect2
- EPHA8 | c.*28A>G | 3'UTR (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- FOLH1B | n.1303T>C | RNA (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- HENMT1 | c.757-425G>A | Intron (SNP) | VAF 8/160 reads (5%) | catalogued as rs1557737829; called by muse, mutect2
- HGD | c.*30T>C | 3'UTR (SNP) | VAF 10/131 reads (8%) | called by muse, mutect2
- HPS3 | c.2590-1011C>T | Intron (SNP) | VAF 17/281 reads (6%) | called by muse, mutect2
- IKZF2 | c.-9A>T | 5'UTR (SNP) | VAF 20/214 reads (9%) | called by muse, mutect2
- LAMA4 | c.503+1444A>G | Intron (SNP) | VAF 33/187 reads (18%) | called by muse, mutect2, varscan2
- LIG1 | c.2385+20G>C | Intron (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- MAP2K2 | c.451-39C>G | Intron (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- MOGS | c.776+16G>C | Intron (SNP) | VAF 9/77 reads (12%) | called by mutect2, varscan2
- NDUFA10 | c.669+32C>G | Intron (SNP) | VAF 24/256 reads (9%) | called by muse, mutect2
- NDUFC2 | c.-10C>T | 5'UTR (SNP) | VAF 7/50 reads (14%) | catalogued as rs760592492, COSV99806611; called by muse, mutect2, varscan2
- NUDC | c.826-26C>T | Intron (SNP) | VAF 34/253 reads (13%) | catalogued as rs370930408; called by muse, mutect2, varscan2
- RIMS1 | c.1679-20593G>A | Intron (SNP) | VAF 8/150 reads (5%) | catalogued as COSV99324061; called by muse, mutect2
- RNY4P30 | chr13:49892030 T>G | 5'Flank (SNP) | VAF 23/224 reads (10%) | called by muse, mutect2, varscan2
- SEPTIN6 | chrX:119616590 G>A | 3'Flank (SNP) | VAF 30/195 reads (15%) | catalogued as rs768159308, COSV100595644; called by muse, mutect2
- SEPTIN6 | chrX:119616592 G>A | 3'Flank (SNP) | VAF 28/188 reads (15%) | called by muse, mutect2
- TTN | c.10360+3076A>T | Intron (SNP) | VAF 37/274 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.10360+2151C>G | Intron (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- VNN3 | c.*177C>G | 3'UTR (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2, varscan2
- XIAP | c.*2710G>T | 3'UTR (SNP) | VAF 16/311 reads (5%) | called by muse, mutect2
- ZNF44 | c.*578A>T | 3'UTR (SNP) | VAF 17/127 reads (13%) | called by muse, mutect2, varscan2
